Somatic mutation profile of tumor specimen TCGA-JY-A93C-01A (aliquot TCGA-JY-A93C-01A-11D-A387-09) from TCGA case TCGA-JY-A93C, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 47.2 years (17,228 days).
Specimen TCGA-JY-A93C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39442627-d89d-4d16-8068-bb510b277ee6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JY-A93C-10A (Blood Derived Normal), aliquot TCGA-JY-A93C-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/591a0834-14b7-4983-9786-c98b4c739f8b

The open-access MAF lists 109 somatic variants for this specimen: 77 protein-altering or splice-affecting, 32 silent.
By variant classification: Missense Mutation 61, Silent 32, Nonsense Mutation 9, Frame Shift Del 3, In Frame Del 2, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYO15A | c.4108C>T p.R1370C | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs878854411; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1728_1730del p.R577del (on ENST00000521381 / NM_181523.3; = p.R307del on NM_181504.4) | In Frame Del (DEL) | VAF 13/40 reads (33%) | hotspot (GDC flag); catalogued as COSV57133583; called by mutect2, pindel, varscan2
- SMAD4 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 32/49 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80338963, CD147870, CM040450, CM041789, CM981228, COSV61683972, COSV61685418, COSV61686083; ClinVar: likely pathogenic / not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 42/53 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AFF2 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 46/56 reads (82%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs368578550, COSV53974983, COSV54006254; called by muse, mutect2, varscan2
- ARHGAP32 | c.5430G>C p.K1810N (on ENST00000310343 / NM_001378025.1; = p.K1461N on NM_014715.4) | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs750227102; called by muse, mutect2, varscan2
- BHLHE22 | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV58862024; called by muse, mutect2
- BMP8B | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs776994850; called by muse, mutect2, varscan2
- CEL | c.1547C>T p.T516M (on ENST00000673714; = p.T513M on NM_001807.6) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs762461399, COSV60826847; called by muse, mutect2, varscan2
- CEP57L1 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.888); catalogued as rs771702036, COSV61244853; called by muse, mutect2, varscan2
- CTNNA3 | c.1489G>A p.V497I | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs368067642; called by muse, mutect2, varscan2
- DOCK11 | c.780G>A p.M260I | Missense Mutation (SNP) | VAF 38/50 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52240511, COSV99353117; called by muse, mutect2, varscan2
- DPY19L2 | c.451-2dup p.X151_splice | Splice Site (INS) | VAF 32/74 reads (43%) | catalogued as rs202064990; called by mutect2, varscan2
- EGFR | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs552062864, COSV51802220; called by muse, mutect2, varscan2
- ENTHD1 | c.261G>T p.K87N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV57322650; called by muse, mutect2, varscan2
- GAS1 | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV53926791; called by muse, mutect2
- GNAZ | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.398); catalogued as rs1221941233, COSV50738562; called by muse, mutect2, varscan2
- GREB1 | c.5780G>A p.R1927H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376907059, COSV52188663; called by muse, mutect2, varscan2
- GRIP2 | c.2452C>T p.H818Y (on ENST00000619221; = p.H721Y on NM_001080423.4) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1253853439, COSV56119532; called by muse, mutect2, varscan2
- GRM8 | c.1917G>A p.M639I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.055); catalogued as rs1390888073, COSV58805588, COSV58869408; called by muse, mutect2, varscan2
- HIVEP2 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs569905766; called by muse, mutect2, varscan2
- HS3ST1 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as rs370389171; called by muse, mutect2, varscan2
- IKBKE | c.1093G>A p.V365I | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs781784265, COSV65624271; called by muse, mutect2, varscan2
- KPNB1 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.073); catalogued as rs1567889630; called by muse, mutect2, varscan2
- MFRP | c.214G>A p.D72N (on ENST00000449574; = p.D448N on NM_031433.4) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs142846614; called by muse, mutect2, varscan2
- MUC6 | c.7069_7071del p.E2357del | In Frame Del (DEL) | VAF 20/78 reads (26%) | catalogued as rs766760246; called by pindel, varscan2
- MYH8 | c.4658C>G p.S1553C | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV101238941; called by muse, mutect2, varscan2
- NAT8 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1291203548, COSV55542308; called by muse, mutect2, varscan2
- NFX1 | c.1441C>T p.R481* | Nonsense Mutation (SNP) | VAF 21/42 reads (50%) | catalogued as rs1451971621; called by muse, mutect2, varscan2
- POTEE | c.2210G>A p.R737H | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.001); catalogued as rs549330020, COSV100388529; called by muse, mutect2, varscan2
- PRKCD | c.1361C>T p.A454V | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV100387899; called by muse, mutect2
- RHEBL1 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.644); catalogued as rs201496596; called by muse, mutect2, varscan2
- RIBC2 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as rs879084546; called by muse, mutect2, varscan2
- SDK1 | c.5074G>A p.V1692M | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.911); catalogued as rs754877724, COSV101270039, COSV67359442; called by muse, mutect2, varscan2
- SEMA5B | c.2861C>T p.T954M | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs1560277290, COSV52094376; called by mutect2, varscan2
- SMOC2 | c.727G>A p.G243S (on ENST00000356284 / NM_001166412.2; = p.G254S on NM_022138.3) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs551280549, COSV62438741; called by muse, mutect2, varscan2
- SPRTN | c.1118C>T p.S373L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs1267679807; called by muse, mutect2, varscan2
- SUCLG2 | c.1192G>A p.V398I | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as rs755049338; called by muse, mutect2, varscan2
- TENM4 | c.5413G>A p.D1805N | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as rs762097519; called by muse, mutect2, varscan2
- TFAP2C | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs138750457; called by muse, mutect2, varscan2
- ZFAND4 | c.2078G>A p.R693H | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371324279; called by muse, mutect2, varscan2
- AAK1 | c.2210C>A p.P737Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AC104389.6 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP32 | c.973C>T p.Q325* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- ARID4B | c.41C>G p.T14S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ATG4B | c.41C>G p.A14G | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- C3orf62 | c.596A>G p.E199G | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- CD248 | c.1765C>T p.Q589* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | called by mutect2, varscan2
- CD38 | c.289C>A p.H97N | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CRLF2 | c.178T>C p.Y60H | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- CRLF2 | c.177C>A p.H59Q | Missense Mutation (SNP) | VAF 28/245 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCBLD1 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- FAM131C | c.711dup p.S238Qfs*43 | Frame Shift Ins (INS) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- FAM170A | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- FNDC11 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- FOXD4L5 | c.242G>A p.S81N | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); called by muse, mutect2
- GSDMC | c.1129A>C p.I377L | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- H2BC18 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.079); called by muse, varscan2
- HTT | c.9189del p.S3064Pfs*25 | Frame Shift Del (DEL) | VAF 27/60 reads (45%) | called by mutect2, pindel, varscan2
- KLF12 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRTAP10-7 | c.43T>A p.Y15N | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MRGPRF | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- NLGN1 | c.470A>C p.N157T | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPEPPS | c.2323G>T p.E775* | Nonsense Mutation (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- OTOP3 | c.1345T>C p.F449L | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SH2D5 | c.1030C>T p.Q344* (on ENST00000444387 / NM_001103161.2; = p.Q260* on NM_001103160.2) | Nonsense Mutation (SNP) | VAF 25/70 reads (36%) | called by muse, mutect2, varscan2
- SLC22A2 | c.1133T>A p.L378Q | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC5A12 | c.89T>A p.I30N | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- SOWAHC | c.574C>T p.L192F | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRRM4 | c.1246T>G p.Y416D | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- TAF7 | c.600_604del p.S201Rfs*10 | Frame Shift Del (DEL) | VAF 18/35 reads (51%) | called by mutect2, pindel, varscan2
- TFAP2D | c.827T>A p.L276* | Nonsense Mutation (SNP) | VAF 24/32 reads (75%) | called by muse, mutect2, varscan2
- TRAIP | c.364C>T p.Q122* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- WDR83 | c.115_122del p.Y39Dfs*5 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | called by mutect2, pindel, varscan2
- ZNF208 | c.1024A>C p.K342Q | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF521 | c.906G>T p.Q302H | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.18); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- ZNF676 | c.464A>T p.H155L (on ENST00000650058; = p.H123L on NM_001001411.3) | Missense Mutation (SNP) | VAF 22/251 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2
- ACTL6A | c.1263G>A p.K421= | Silent (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- AHDC1 | c.1335G>A p.P445= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs980115486; called by muse, mutect2
- ARHGAP32 | c.3102G>A p.P1034= (on ENST00000310343 / NM_001378025.1; = p.P685= on NM_014715.4) | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs761748472, COSV59849015; called by muse, mutect2, varscan2
- CNTN4 | c.2112G>A p.A704= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs759314373; called by muse, mutect2, varscan2
- DCAF12L2 | c.1062G>T p.R354= | Silent (SNP) | VAF 13/16 reads (81%) | catalogued as COSV63584214; called by muse, mutect2, varscan2
- DERL3 | c.135G>C p.P45= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs1482515145; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.999C>T p.N333= | Silent (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- ENKD1 | c.1002C>T p.I334= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as COSV54666608, COSV54666814; called by muse, mutect2, varscan2
- FAM181A | c.237G>A p.A79= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs769831279; called by muse, mutect2, varscan2
- FBXO31 | c.483C>T p.N161= | Silent (SNP) | VAF 14/18 reads (78%) | catalogued as rs773883607, COSV61149373; called by muse, mutect2, varscan2
- FRMD3 | c.72C>T p.S24= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as rs753599775; called by muse, mutect2, varscan2
- GPR55 | c.369C>T p.I123= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs780921301; called by muse, mutect2, varscan2
- H2AB1 | c.249C>T p.I83= | Silent (SNP) | VAF 61/140 reads (44%) | called by muse, mutect2, varscan2
- LRRCC1 | c.1890C>T p.D630= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as rs745393978; called by muse, mutect2
- MGA | c.5256T>G p.P1752= (on ENST00000219905 / NM_001164273.1; = p.P1543= on NM_001080541.2) | Silent (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- PABPC3 | c.75G>A p.A25= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as rs746175919; called by muse, mutect2, varscan2
- PAX7 | c.1461C>T p.L487= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs748193866, COSV69314322; called by muse, mutect2, varscan2
- PCDH1 | c.924C>T p.D308= | Silent (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- PSMA3 | c.561C>T p.C187= | Silent (SNP) | VAF 39/112 reads (35%) | called by muse, mutect2, varscan2
- RPRM | c.126G>A p.A42= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV57988751, COSV57988967; called by muse, mutect2, varscan2
- RRBP1 | c.3744C>T p.S1248= (on ENST00000377813 / NM_001365613.2; = p.S815= on NM_004587.3) | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs371408403; called by mutect2, varscan2
- RTP2 | c.390C>T p.Y130= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs376471256; called by muse, mutect2, varscan2
- SLC39A8 | c.400C>T p.L134= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV100765882; called by muse, mutect2, varscan2
- SLC7A13 | c.810C>T p.L270= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV52537276; called by muse, mutect2, varscan2
- SLCO6A1 | c.117G>T p.P39= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV65808252; called by muse, mutect2, varscan2
- SYNE1 | c.7959T>G p.T2653= (on ENST00000367255 / NM_182961.4; = p.T2660= on NM_033071.3) | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as rs1281382839; called by muse, mutect2, varscan2
- TMEM42 | c.247C>T p.L83= | Silent (SNP) | VAF 29/88 reads (33%) | called by muse, mutect2, varscan2
- USP40 | c.1497A>G p.P499= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as rs752446962; called by muse, mutect2, varscan2
- ZBED1 | c.435C>T p.D145= | Silent (SNP) | VAF 52/81 reads (64%) | catalogued as rs777092860; called by muse, mutect2, varscan2
- ZC3H4 | c.3423T>C p.S1141= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs1453608336; called by muse, mutect2, varscan2
- ZNF23 | c.1368C>T p.A456= | Silent (SNP) | VAF 27/39 reads (69%) | catalogued as rs907619748; called by muse, mutect2, varscan2
- ZNF234 | c.1854C>T p.H618= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs1291635196; called by muse, mutect2, varscan2
